Somatic mutation profile of tumor specimen TCGA-L5-A4OP-01A (aliquot TCGA-L5-A4OP-01A-11D-A27G-09) from TCGA case TCGA-L5-A4OP, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 68.0 years (24,829 days).
Specimen TCGA-L5-A4OP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b313d086-7d1e-48c8-a7f8-43d8d149ed9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OP-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OP-11A-11D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ffd48e4-53e5-4633-bbe5-8979d5adaa35

The open-access MAF lists 121 somatic variants for this specimen: 98 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 21, Nonsense Mutation 4, In Frame Del 2, Frame Shift Ins 1, Splice Region 1, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 6/10 reads (60%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- CDKN2A | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as CM970251, COSV100446243, COSV58683273, COSV58688196; called by muse, varscan2
- KMT2A | c.3790C>T p.R1264* | Nonsense Mutation (SNP) | VAF 9/10 reads (90%) | hotspot (GDC flag); catalogued as rs1555039343, COSV63282990; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.715_720del p.N239_S240del | In Frame Del (DEL) | VAF 93/180 reads (52%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AEBP1 | c.995C>T p.T332I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs532526583; called by muse, mutect2, varscan2
- AGBL5 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs781286009, COSV64080852; called by muse, mutect2, varscan2
- AHCYL2 | c.477G>A p.A159= | Splice Region (SNP) | VAF 9/30 reads (30%) | catalogued as rs564152454; called by muse, mutect2, varscan2
- BARD1 | c.1816C>A p.H606N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53615398; called by muse, mutect2, varscan2
- BNIP5 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV101465190; called by muse, mutect2, varscan2
- C1RL | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs777553132, COSV56925037; called by muse, mutect2, varscan2
- CACNA1H | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1047092055; called by muse, mutect2, varscan2
- CAV1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs769406995, COSV61952793; called by muse, mutect2, varscan2
- CCKBR | c.1210A>G p.T404A | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs76115904; called by muse, mutect2, varscan2
- CDH11 | c.1282G>C p.D428H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV51778517; called by muse, mutect2
- CHM | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as CD941644, COSV63300908; called by muse, mutect2, varscan2
- COL19A1 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs149953250; called by muse, mutect2, varscan2
- COL24A1 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs763869154, COSV100993476; called by muse, mutect2, varscan2
- CSMD3 | c.9339G>C p.Q3113H (on ENST00000297405 / NM_001363185.1; = p.Q2944H on NM_052900.3) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV52261049; called by muse, mutect2, varscan2
- CTAGE6 | c.823A>G p.M275V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1444682282; called by mutect2, varscan2
- DCC | c.2650C>T p.R884W | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768330985, COSV100499884; called by muse, mutect2, varscan2
- DHRS9 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs760219749, COSV59139552; called by muse, mutect2, varscan2
- DLEC1 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs776453700; called by muse, mutect2, varscan2
- DNAH9 | c.5318G>A p.R1773Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759673753, COSV52335166; called by muse, mutect2, varscan2
- FCER2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs755933015; called by muse, mutect2, varscan2
- GRM3 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs774266273, COSV64467897; called by muse, mutect2, varscan2
- HECTD4 | c.6823C>T p.R2275W | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1277148508, COSV66388792; called by muse, mutect2, varscan2
- HIVEP2 | c.4294G>A p.V1432M | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs920504937, COSV50077305; called by muse, mutect2, varscan2
- KRT24 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs369972316, COSV99232060; called by muse, mutect2
- LRP1B | c.4490A>C p.K1497T | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758430451, COSV101255116, COSV67192589; called by muse, mutect2, varscan2
- LRRTM4 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422872769, COSV69140187; called by muse, mutect2, varscan2
- MAGEE2 | c.803A>C p.K268T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV100973264; called by mutect2, varscan2
- NAV3 | c.2480T>C p.L827P | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1374970034; called by muse, mutect2, varscan2
- NBEA | c.4655G>A p.R1552Q | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs1397311063; called by muse, mutect2, varscan2
- OR13C5 | c.817T>G p.L273V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV66164122; called by muse, mutect2, varscan2
- OR56B1 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57722468; called by muse, mutect2, varscan2
- PAMR1 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as rs777943313; called by muse, mutect2, varscan2
- POF1B | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs148186919, COSV53138242; called by muse, mutect2, varscan2
- PORCN | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.863); catalogued as rs267606466; called by muse, mutect2, varscan2
- PPP1R13B | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as rs749124281, COSV52452574; called by muse, mutect2, varscan2
- PRKAR2B | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99708458; called by muse, mutect2, varscan2
- PTPRS | c.3532G>A p.D1178N | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs774597513; called by muse, mutect2, varscan2
- RERG | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs866215454; called by muse, mutect2, varscan2
- SACS | c.6871G>T p.D2291Y | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs1170939021; called by muse, mutect2, varscan2
- SALL1 | c.3737C>T p.A1246V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs768727477; called by muse, mutect2, varscan2
- SELE | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.193); catalogued as rs139816972; called by muse, mutect2, varscan2
- SEPTIN6 | c.1032G>T p.Q344H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1178428302; called by muse, mutect2, varscan2
- SERPINA12 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100369559; called by muse, mutect2, varscan2
- SLC38A5 | c.365C>A p.A122E | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV58333315; called by muse, mutect2, varscan2
- SNED1 | c.1852G>A p.G618R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1437622728; called by muse, mutect2, varscan2
- TDRD10 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs978647333, COSV100872999; called by muse, mutect2, varscan2
- UNC13C | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs536918048, COSV52844678; called by muse, mutect2, varscan2
- WNT7B | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1158594747; called by muse, mutect2, varscan2
- ZFR2 | c.2399G>A p.R800Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762666960; called by muse, mutect2, varscan2
- ADAMTS16 | c.1471C>A p.L491I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADD2 | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALMS1 | c.56A>C p.E19A | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ATP2B3 | c.3394C>A p.P1132T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CACNA1F | c.2505A>C p.E835D | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.138); called by muse, mutect2
- CCDC150 | c.846A>T p.K282N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- CHRM2 | c.233A>C p.N78T | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DCC | c.2743A>G p.M915V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DNAH7 | c.6007C>A p.L2003I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EXOC4 | c.31A>G p.R11G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- FUS | c.1204_1218del p.S402_G406del | In Frame Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, varscan2
- GPR141 | c.500T>A p.F167Y | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLA-B | c.1070A>C p.D357A | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPU | c.2027C>T p.P676L (on ENST00000283179; = p.P738L on NM_004501.3) | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HTR2C | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCND2 | c.1603A>C p.K535Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- KIF4A | c.1925T>A p.M642K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.006); called by mutect2, varscan2
- LIMCH1 | c.890G>A p.S297N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- LRRN4 | c.779G>A p.C260Y | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- LSP1 | c.187A>G p.M63V | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- MASP1 | c.312G>C p.Q104H | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MEOX2 | c.532A>C p.N178H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- MYO15A | c.4426T>C p.F1476L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- OPRPN | c.170T>G p.L57R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR4C12 | c.496T>G p.F166V | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDH18 | c.2921C>A p.A974E | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.94); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PCDHB3 | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB3 | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.975G>C p.Q325H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCM1 | c.1598C>G p.S533* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- PPARGC1A | c.459C>A p.N153K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- PSTPIP1 | c.385A>T p.S129C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- PXDNL | c.2022A>C p.E674D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RHCG | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- RPRD2 | c.3561C>G p.N1187K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SH2B3 | c.866T>C p.V289A | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.124); called by muse, mutect2
- SLAMF1 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SUPT20HL1 | c.509C>A p.T170K | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- THAP11 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TKTL1 | c.964T>A p.S322T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TRIR | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WEE2 | c.1393-1G>A p.X465_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- WNT3 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- XPO7 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- ZBTB11 | c.3031C>T p.L1011F | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC82 | c.1359T>C p.N453= | Silent (SNP) | VAF 20/32 reads (63%) | called by muse, mutect2, varscan2
- CFAP206 | c.1725A>G p.P575= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1271434350; called by mutect2, varscan2
- CRY2 | c.1467C>T p.I489= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as rs933484537; called by muse, mutect2, varscan2
- FPGT | c.1008C>T p.V336= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs1427352719, COSV63843620; called by muse, mutect2, varscan2
- GCNA | c.798C>T p.D266= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as rs995093975; called by muse, mutect2, varscan2
- IFT122 | c.1470G>T p.V490= (on ENST00000348417 / NM_052989.3; = p.V431= on NM_018262.4) | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- KAT14 | c.177C>G p.L59= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100890044; called by muse, mutect2, varscan2
- LRRTM4 | c.1605C>T p.I535= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV69151719; called by muse, mutect2, varscan2
- MRC2 | c.657C>T p.Y219= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs564657391, COSV57640517; called by muse, mutect2, varscan2
- MVP | c.2172G>A p.A724= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs749354165; called by muse, mutect2, varscan2
- NFYB | c.339C>T p.I113= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99527210; called by muse, mutect2, varscan2
- OR10H3 | c.42C>T p.L14= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV59944939; called by muse, mutect2, varscan2
- P2RY10 | c.846C>T p.I282= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs781260102, COSV50680637; called by muse, mutect2, varscan2
- PRKN | c.924A>G p.G308= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- RB1CC1 | c.864G>A p.Q288= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs747652097; called by muse, mutect2, varscan2
- SDK1 | c.4521C>A p.S1507= | Silent (SNP) | VAF 7/64 reads (11%) | called by mutect2, varscan2
- WFIKKN1 | c.180G>A p.A60= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs568979205; called by muse, mutect2, varscan2
- WNT3 | c.309C>T p.P103= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99843325; called by muse, mutect2, varscan2
- XIRP2 | c.8892C>T p.N2964= (on ENST00000628543; = p.N3139= on NM_152381.6) | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs556211010, COSV54682772, COSV54692150; called by muse, mutect2, varscan2
- ZNF808 | c.1860G>A p.E620= | Silent (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- ZNF875 | c.921G>T p.G307= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- NR0B1 | c.1169-1007T>C | Intron (SNP) | VAF 26/92 reads (28%) | catalogued as rs1311980782, COSV66764360; called by muse, mutect2, varscan2
- RPL26P30 | n.582G>A | RNA (SNP) | VAF 31/44 reads (70%) | catalogued as rs550965880; called by muse, mutect2, varscan2
